Somatic mutation profile of tumor specimen TARGET-20-PAMVKZ-09A (aliquot TARGET-20-PAMVKZ-09A-02D) from TARGET case TARGET-20-PAMVKZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,934 days).
Specimen TARGET-20-PAMVKZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a90207-6eb3-43d7-91f1-4f9cc05bb811.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAMVKZ-14A (Bone Marrow Normal), aliquot TARGET-20-PAMVKZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a63bd313-466f-4656-a234-003a3ae1617d

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/114 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SPI1 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV57026349; called by muse, mutect2, varscan2
